MMRF case MMRF_1454 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d074356e-199c-49fd-8a2a-57419505bca2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.7 years (19,632 days); ISS stage: II; Days to last known disease status: 1,331 days (3.6 years); Days to last follow up: 1,331 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 337 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,041 days (2.9 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 160 days; Days to treatment end: 160 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days; Days to treatment end: 524 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 0): M Protein 3.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 62.9 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.85 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 9.9 g/dL; Glucose 4.24 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 78 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.154 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 4.29 mmol/L.
- Day 182 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.082 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.112 mg/dL; Immunoglobulin G 5.31 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.35 mmol/L.
- Day 272 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.087 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.462 mg/dL; Immunoglobulin G 7.62 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.41 g/dL; Glucose 4.73 mmol/L.
- Day 377 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.66 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.18 mmol/L.
- Day 468 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.2 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.35 mmol/L.
- Day 559 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.3 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 657 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 19.3 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 6.11 mmol/L.
- Day 748 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.888 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.4 mmol/L.
- Day 841 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.956 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.
- Day 930 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 9.45 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.79 mmol/L.
- Day 1,098 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.912 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 1,179 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.807 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 4.24 mmol/L.
- Day 1,331: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.849 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.906 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day -27: Weight: 80 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1454_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1454_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
